Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A265, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A265-06A (Metastatic).

ICD-0-3

Melanoma, malignant, NOS 8720/3

Site: lymph nodes, axillary C77.3 *hw*
4/27/11

SPECIMENS:

A. LEFT AXILLARY MASS LEVELS 1, 2, 3

DIAGNOSIS:

LEFT AXILLARY MASS, LEVELS 1,2,3:

- METASTATIC MALIGNANT MELANOMA INVOLVING TEN OUT OF TWENTY
EIGHT AXILLARY LYMPH NODES, (10/28) SEE NOTE.

NOTE: Level 2 lymph node shows enlarged lymph node extensively involved by metastatic tumor
(measuring 7 x 6 x 4.5 cm).

Lymph nodes identified:

Level I: 0/5 Negative

Level II: 5/10 Positive

Level III: 5/13 Positive

Some lymph nodes show tumor cells within lymphatic vessels. There is extension to perinodal fat.
See also path report number .

SPECIMEN(S):

A. LEFT AXILLARY MASS LEVELS 1, 2, 3

CLINICAL HISTORY:

male with golf ball size lump left axilla-bx -consistent with melanoma. Pet scan-elevated
activity left axilla with several foci in axillary and periclavicular region. CT-chest and abd-5cm left
axillary mass with enlarged lymph nodes.

GROSS DESCRIPTION:

A. LEFT AXILLARY MASS, LEVELS 1, 2, 3

Received fresh for tissue procurement and labelled "left axilla mass" is a fatty adipose mass with an
ellipse of skin. The entire specimen measures 25x15x6cm. The skin is 11x3cm with a central scar,
4cm. There are 3 stitches attached to the specimen indicating level 1-single stitch, level 2-double stitch
and level 3-three stitches. Serial sections reveal multiple enlarged lymph nodes grossly involved by
tumor mass, ranging from 0.5cm to 7x6x4.5cm. The largest lymph node is gray-white, homogeneous
and solid, confluent with multiple lymph nodes located at level 2 area. Section of the skin is
unremarkable. The tumor involved lymph nodes are submitted in representative sections.

Representative sections are submitted in 21 cassettes.

Cassette 1-3: level 1, multiple lymph nodes

Cassette 4-14: level 2 (4,5,6-1 enlarged lymph node representative sections)

Cassette 15-21: level 3 lymph nodes

Gross Dictation:., Pathology Fellow,
Microscopic/Diagnostic Dictation: Pathologist.
Final Review: Pathologist,
Final: Pathologist

Source: NCI Genomic Data Commons file 36255cd1-a433-40aa-8abc-03046938adf2 (TCGA-GN-A265.B268C2CF-D98F-4A7F-A708-244442C0B169.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).